CGCI case BLGSP-71-29-00537 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/8c2de23e-f1cc-4c8a-b9d7-6513e4955434

Demographics
Sex at birth: female.

Biospecimens (1 sample)
- Sample BLGSP-71-29-00537-50A: Sample type: Cell Lines; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Derived Cell Line; Preservation method: Frozen.
